Somatic mutation profile of tumor specimen TARGET-30-PAPWFY-01A (aliquot TARGET-30-PAPWFY-01A-01D) from TARGET case TARGET-30-PAPWFY, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.1 years (757 days).
Specimen TARGET-30-PAPWFY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c018930a-27d6-467d-8cae-3d6a11ab5edf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPWFY-10A (Blood Derived Normal), aliquot TARGET-30-PAPWFY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d21f789-f3ad-43f5-b34a-0d6e2eefbff5

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.10576T>C p.S3526P | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV71672006; called by muse, mutect2, varscan2
- LARP6 | c.717G>T p.L239= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs754090085, COSV54579008; called by mutect2, varscan2
- OR2Z1 | c.123C>A p.G41= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs566366007, COSV60691678; called by muse, mutect2, varscan2
